Somatic mutation profile of tumor specimen ALCH-B2XA-TTP1-A (aliquot ALCH-B2XA-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B2XA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.4 years (25,719 days).
Specimen ALCH-B2XA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3841e8e4-8b13-4e0e-b49e-29ef589406f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2XA-NB1-A (Blood Derived Normal), aliquot ALCH-B2XA-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4ae79fe-ff38-481a-ad14-4ff139d39e62

The open-access MAF lists 1,459 somatic variants for this specimen: 993 protein-altering or splice-affecting, 287 silent, 179 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 867, Silent 287, Intron 84, Nonsense Mutation 55, RNA 36, Frame Shift Del 26, 5'UTR 25, Splice Site 22, 3'UTR 18, Splice Region 13, 5'Flank 8, 3'Flank 8.

Variants (750 of 1,459; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 40/84 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762846821, CM951223, COSV52667239, COSV52783646, COSV53625267; called by muse, mutect2, varscan2
- ABCB5 | c.1658C>G p.S553C (on ENST00000404938 / NM_001163941.2; = p.S108C on NM_178559.6) | Missense Mutation (SNP) | VAF 134/313 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51710989, COSV51713608; called by muse, mutect2, varscan2
- ACACB | c.3132G>C p.E1044D | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as rs1383997643; called by muse, mutect2, varscan2
- ACE | c.919G>C p.D307H | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52003049; called by muse, mutect2, varscan2
- ACO2 | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); catalogued as rs1484434122; called by mutect2, varscan2
- ACTRT1 | c.216C>A p.Y72* | Nonsense Mutation (SNP) | VAF 29/59 reads (49%) | catalogued as COSV64419777; called by muse, mutect2, varscan2
- ADAM19 | c.738+3G>A | Splice Region (SNP) | VAF 57/122 reads (47%) | catalogued as COSV99976665; called by muse, mutect2, varscan2
- ADAMTS12 | c.1916C>A p.P639H | Missense Mutation (SNP) | VAF 69/150 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs552049994; called by muse, mutect2, varscan2
- ADAMTS12 | c.203C>A p.S68* | Nonsense Mutation (SNP) | VAF 64/323 reads (20%) | catalogued as COSV61270002; called by muse, mutect2, varscan2
- ADAMTS16 | c.3356C>A p.P1119Q | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.047); catalogued as COSV56978288; called by muse, mutect2, varscan2
- ADAMTS2 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 85/191 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as rs765909622; called by muse, mutect2, varscan2
- ADAMTS5 | c.1918C>A p.Q640K | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as COSV53179920; called by muse, mutect2, varscan2
- ADAMTSL4 | c.3074G>A p.C1025Y | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1459602795; called by muse, mutect2, varscan2
- ADCY10 | c.3912C>A p.F1304L | Missense Mutation (SNP) | VAF 102/604 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV63239708; called by muse, mutect2, varscan2
- AJM1 | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as rs1276043391, COSV56032983; called by muse, mutect2, varscan2
- AK9 | c.3643A>G p.R1215G | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs1430106615; called by muse, mutect2, varscan2
- AKAP6 | c.6679G>C p.E2227Q | Missense Mutation (SNP) | VAF 36/632 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.558); catalogued as COSV55212620; called by muse, mutect2
- ANGPT4 | c.1003C>A p.R335S | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs775701631, COSV101124809; called by muse, mutect2, varscan2
- ANK3 | c.9689G>T p.R3230L | Missense Mutation (SNP) | VAF 24/291 reads (8%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV55059450, COSV55080545; called by muse, mutect2
- ANK3 | c.1199G>A p.G400D | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1248978535; called by muse, mutect2, varscan2
- ANKRD11 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 32/235 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV56357457; called by muse, mutect2, varscan2
- ANKRD20A2P | c.140C>A p.A47E | Missense Mutation (SNP) | VAF 68/371 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as rs199914729; called by muse, mutect2, varscan2
- ANKS1B | c.1724C>A p.T575K | Missense Mutation (SNP) | VAF 207/373 reads (55%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV61384423; called by muse, mutect2, varscan2
- AP002512.3 | c.1037C>A p.S346Y | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54409197; called by muse, mutect2
- AP3B2 | c.2009G>C p.R670T | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.13); catalogued as rs778950470; called by muse, mutect2, varscan2
- ARHGAP5 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 22/444 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.206); catalogued as COSV100565175; called by muse, mutect2
- ARID1B | c.3007A>G p.M1003V | Missense Mutation (SNP) | VAF 165/334 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1364487861; called by muse, mutect2, varscan2
- ATAD2B | c.2743G>T p.A915S | Missense Mutation (SNP) | VAF 121/185 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as COSV53195864; called by muse, mutect2, varscan2
- ATP10A | c.1574G>T p.S525I | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63526564; called by muse, mutect2, varscan2
- ATP2A3 | c.1707del p.P571Qfs*21 | Frame Shift Del (DEL) | VAF 22/175 reads (13%) | catalogued as COSV59233346; called by mutect2, pindel, varscan2
- B3GNT9 | c.387C>G p.F129L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV54628655; called by muse, mutect2, varscan2
- BCR | c.1735G>A p.D579N | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs760590010, COSV59928493; called by muse, mutect2, varscan2
- BDKRB2 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as rs751331696, COSV100021056; called by muse, mutect2
- BTBD18 | c.916_919del p.E306Hfs*136 | Frame Shift Del (DEL) | VAF 26/213 reads (12%) | catalogued as rs1354395627; called by mutect2, pindel
- C10orf71 | c.3124G>T p.G1042W | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1460299701; called by muse, mutect2, varscan2
- C1R | c.920G>T p.G307V (on ENST00000536053 / NM_001354346.2; = p.G293V on NM_001733.7) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101599224, COSV73293837; called by muse, mutect2, varscan2
- C2CD4A | c.848G>A p.G283D | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.865); catalogued as rs779290185; called by muse, mutect2, varscan2
- C3 | c.3959G>T p.R1320L | Missense Mutation (SNP) | VAF 89/208 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1426625425, COSV55570849; called by muse, mutect2, varscan2
- CACNA1H | c.3538G>C p.E1180Q | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.838); catalogued as COSV62000437; called by muse, mutect2, varscan2
- CACNA2D1 | c.1414C>T p.Q472* | Nonsense Mutation (SNP) | VAF 65/628 reads (10%) | catalogued as rs868040937; called by muse, mutect2, varscan2
- CALHM5 | c.188T>C p.L63P | Missense Mutation (SNP) | VAF 147/329 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1252286717; called by muse, mutect2, varscan2
- CATSPERB | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs756301845; called by muse, mutect2, varscan2
- CCDC39 | c.1199G>T p.G400V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as rs748151034, COSV99870604; called by muse, mutect2, varscan2
- CCKBR | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777692103, COSV58099117, COSV58099888; called by muse, mutect2, varscan2
- CCN6 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100036940; called by muse, mutect2
- CCT8L2 | c.1384G>T p.D462Y | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV63463726; called by muse, mutect2, varscan2
- CCT8L2 | c.167G>C p.R56P | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV63463642; called by muse, mutect2, varscan2
- CDC14C | c.1260G>C p.W420C (on ENST00000428251; = p.W313C on NM_152627.3) | Missense Mutation (SNP) | VAF 108/522 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754876673; called by muse, mutect2, varscan2
- CDH10 | c.244del p.Q82Kfs*56 | Frame Shift Del (DEL) | VAF 44/203 reads (22%) | catalogued as COSV100051422, COSV52574911; called by mutect2, pindel, varscan2
- CECR2 | c.889A>T p.T297S (on ENST00000342247 / NM_001290047.2; = p.T134S on NM_001290046.1) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.098); catalogued as rs940161101; called by muse, mutect2, varscan2
- CENPC | c.1249A>G p.I417V | Missense Mutation (SNP) | VAF 90/304 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs142565656; called by muse, mutect2, varscan2
- CHAT | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 139/278 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs376641216; called by muse, mutect2, varscan2
- CHD2 | c.1880C>T p.S627F | Missense Mutation (SNP) | VAF 156/474 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67711659; called by muse, mutect2, varscan2
- CHRNB4 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs770241594; called by muse, mutect2, varscan2
- CHST13 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.544); catalogued as COSV100081454; called by muse, mutect2, varscan2
- CNGA2 | c.1495C>A p.L499M | Missense Mutation (SNP) | VAF 75/108 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1569428697, COSV61705594; called by muse, mutect2, varscan2
- CNNM1 | c.2183G>T p.R728L | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.737); catalogued as COSV63202919; called by muse, mutect2, varscan2
- CRB1 | c.1844G>T p.G615V | Missense Mutation (SNP) | VAF 61/497 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM132579; called by muse, mutect2, varscan2
- CSMD1 | c.1085G>T p.G362V | Missense Mutation (SNP) | VAF 26/287 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371204053; called by muse, mutect2
- CSMD3 | c.4015G>C p.D1339H (on ENST00000297405 / NM_001363185.1; = p.D1235H on NM_052900.3) | Missense Mutation (SNP) | VAF 122/599 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV52126727, COSV99836525; called by muse, mutect2, varscan2
- CSMD3 | c.409G>T p.G137* | Nonsense Mutation (SNP) | VAF 88/532 reads (17%) | catalogued as COSV99819635; called by muse, mutect2, varscan2
- CTSE | c.889G>A p.D297N (on ENST00000360218; = p.D292N on NM_001910.4) | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs370816867; called by muse, varscan2
- CYBA | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 76/168 reads (45%) | catalogued as rs1211113285, CD082085; called by muse, varscan2
- CYP2C9 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 187/471 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs762239445, CM1412013; called by muse, mutect2, varscan2
- DACH1 | c.1943C>A p.T648N (on ENST00000619232 / NM_001366712.1; = p.T394N on NM_004392.6) | Missense Mutation (SNP) | VAF 87/297 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as rs776696278; called by muse, mutect2, varscan2
- DCHS1 | c.3151A>G p.S1051G | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); catalogued as COSV55042979; called by muse, mutect2, varscan2
- DCHS2 | c.1569G>T p.E523D | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.625); catalogued as COSV59737160; called by muse, mutect2, varscan2
- DCLK1 | c.1581A>T p.K527N | Missense Mutation (SNP) | VAF 64/327 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55174043; called by muse, mutect2, varscan2
- DEFA4 | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.281); catalogued as rs1214046288, COSV52405211; called by muse, mutect2, varscan2
- DEFA5 | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs746961735; called by muse, mutect2, varscan2
- DLG5 | c.1784G>T p.R595L | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV64946878; called by muse, mutect2
- DLGAP2 | c.1082C>A p.P361H | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV101421293, COSV70102736; called by muse, mutect2
- DMC1 | c.610G>T p.D204Y | Missense Mutation (SNP) | VAF 94/307 reads (31%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.616); catalogued as COSV53258305; called by muse, mutect2, varscan2
- DNAH11 | c.3255G>A p.Q1085= | Splice Region (SNP) | VAF 17/126 reads (13%) | catalogued as rs1177556449; called by muse, mutect2, varscan2
- DNAH3 | c.11221G>A p.D3741N | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369301705; called by muse, mutect2, varscan2
- DNAH5 | c.9762G>C p.K3254N | Missense Mutation (SNP) | VAF 106/346 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as COSV54227538; called by muse, mutect2, varscan2
- DPP9 | c.1020G>T p.Q340H (on ENST00000598800; = p.Q369H on NM_139159.5) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.057); catalogued as rs1486577324; called by muse, mutect2, varscan2
- DSCAM | c.3515G>T p.G1172V | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68028733; called by muse, mutect2, varscan2
- DSCAML1 | c.2881C>G p.R961G (on ENST00000321322; = p.R901G on NM_020693.4) | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV58398063; called by muse, mutect2, varscan2
- DSE | c.1288A>G p.I430V | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as rs1198223713; called by muse, mutect2
- ECEL1 | c.1973C>T p.T658I | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs766889105; called by muse, mutect2, varscan2
- EFCAB6 | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376790303; called by muse, mutect2, varscan2
- ELFN1 | c.484G>T p.D162Y | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV70036408; called by muse, mutect2, varscan2
- EML2 | c.1099A>T p.T367S | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as rs1301220567; called by muse, mutect2, varscan2
- EPPK1 | c.2072A>T p.Y691F | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782731105; called by muse, mutect2, varscan2
- ERICH3 | c.4342C>G p.Q1448E | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.037); catalogued as COSV58599160; called by muse, mutect2, varscan2
- EZHIP | c.1117G>T p.G373W | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100539847, COSV57956272; called by muse, mutect2, varscan2
- F5 | c.4281G>A p.M1427I | Missense Mutation (SNP) | VAF 96/248 reads (39%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1485361538; called by muse, mutect2, varscan2
- FAM107B | c.131G>T p.G44V (on ENST00000378458 / NM_001320737.1; = p.G219V on NM_031453.3) | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1388153146; called by muse, mutect2, varscan2
- FAM83B | c.2260G>T p.E754* | Nonsense Mutation (SNP) | VAF 9/184 reads (5%) | catalogued as COSV100174295; called by muse, mutect2
- FANK1 | c.471C>T p.T157= | Splice Region (SNP) | VAF 54/156 reads (35%) | catalogued as rs756239873, COSV100904803; called by muse, mutect2, varscan2
- FAT1 | c.1595G>T p.R532L | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV101499218; called by muse, mutect2, varscan2
- FBL | c.778T>C p.F260L | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as rs1315876412; called by muse, mutect2
- FBN2 | c.337+1G>C p.X113_splice | Splice Site (SNP) | VAF 150/376 reads (40%) | catalogued as rs1342394361; called by muse, mutect2
- FBN2 | c.336C>T p.V112= | Splice Region (SNP) | VAF 156/389 reads (40%) | catalogued as rs1269124844; called by muse, mutect2
- FBXO28 | c.857G>T p.R286L | Missense Mutation (SNP) | VAF 23/383 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV64801016; called by muse, mutect2
- FCAR | c.848C>G p.P283R | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.86); catalogued as rs1469018011; called by muse, mutect2, varscan2
- FCGR3A | c.165C>A p.D55E | Missense Mutation (SNP) | VAF 202/954 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as COSV63459261; called by muse, mutect2, varscan2
- FER1L6 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.761); catalogued as COSV67547865; called by muse, mutect2
- FGF4 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 204/294 reads (69%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV51450013; called by muse, mutect2, varscan2
- FGFR3 | c.473G>C p.R158P | Missense Mutation (SNP) | VAF 55/95 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53410235; called by muse, mutect2, varscan2
- FKBP10 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0.085); catalogued as rs370277647; called by muse, mutect2, varscan2
- FLNA | c.4804G>A p.G1602S | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61047712; called by muse, mutect2, varscan2
- FLT3 | c.838G>C p.G280R | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV54048385; called by muse, mutect2, varscan2
- FMN1 | c.3880G>T p.E1294* (on ENST00000616417 / NM_001277313.2; = p.E1071* on NM_001103184.4) | Nonsense Mutation (SNP) | VAF 169/322 reads (52%) | catalogued as COSV100569283, COSV57922647; called by muse, mutect2, varscan2
- FMN1 | c.665C>A p.P222Q | Missense Mutation (SNP) | VAF 90/150 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.751); catalogued as COSV58001278; called by muse, mutect2, varscan2
- FN1 | c.5461C>T p.R1821C | Missense Mutation (SNP) | VAF 32/261 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764193807; called by muse, mutect2, varscan2
- FOSB | c.350C>A p.A117E | Missense Mutation (SNP) | VAF 57/254 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV62278355; called by muse, mutect2, varscan2
- FOXD2 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 51/328 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1232327975; called by muse, mutect2, varscan2
- FPR2 | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 77/231 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.209); catalogued as rs927373965; called by muse, mutect2, varscan2
- FSD2 | c.139G>T p.V47F | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV100575328; called by muse, mutect2, varscan2
- FUOM | c.92C>G p.A31G | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.162); catalogued as rs867250660; called by muse, mutect2, varscan2
- GAS8 | c.341C>G p.T114R | Missense Mutation (SNP) | VAF 85/162 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.247); catalogued as rs760230699; called by muse, mutect2, varscan2
- GAST | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV61475727; called by muse, mutect2, varscan2
- GATA3 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 177/368 reads (48%) | catalogued as COSV60516718; called by muse, mutect2, varscan2
- GATA4 | c.1144del p.Q382Rfs*22 | Frame Shift Del (DEL) | VAF 15/85 reads (18%) | catalogued as COSV58735507; called by mutect2, pindel, varscan2
- GDF6 | c.1137G>T p.E379D | Missense Mutation (SNP) | VAF 248/519 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.407); catalogued as COSV54627048; called by muse, varscan2
- GGA2 | c.860C>T p.T287I | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.119); catalogued as rs1393383751; called by muse, mutect2, varscan2
- GLYR1 | c.880A>C p.T294P | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58926516; called by muse, mutect2, varscan2
- GPAM | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 37/343 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV62080744; called by muse, mutect2, varscan2
- GPR152 | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 152/232 reads (66%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs138622501; called by muse, mutect2, varscan2
- GRIA2 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 36/97 reads (37%) | catalogued as COSV52389715; called by muse, mutect2, varscan2
- GRIN2B | c.3592del p.E1198Rfs*4 | Frame Shift Del (DEL) | VAF 62/150 reads (41%) | catalogued as COSV101662917; called by mutect2, pindel, varscan2
- GSX2 | c.637C>A p.Q213K | Missense Mutation (SNP) | VAF 61/105 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58843677; called by muse, mutect2, varscan2
- GXYLT2 | c.1104C>A p.D368E | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as rs569607352, COSV67473860; called by muse, mutect2, varscan2
- HNF1A | c.849G>T p.M283I | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV57465733; called by muse, mutect2, varscan2
- HRNR | c.1314C>G p.S438R | Missense Mutation (SNP) | VAF 140/436 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.452); catalogued as COSV64263313; called by muse, mutect2, varscan2
- HSD11B1 | c.636_637del p.V214Sfs*45 | Frame Shift Del (DEL) | VAF 77/540 reads (14%) | catalogued as rs1370655076; called by pindel, varscan2
- IFNA13 | c.244C>A p.H82N | Missense Mutation (SNP) | VAF 44/243 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV101489468; called by muse, varscan2
- IFRD1 | c.795G>T p.E265D | Missense Mutation (SNP) | VAF 32/363 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV50043993; called by muse, mutect2
- IGHV3-49 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 82/221 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.143); catalogued as rs782738461; called by muse, varscan2
- IGHV3-74 | c.152A>G p.Y51C | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.164); catalogued as rs771871886; called by muse, mutect2
- IGLV5-45 | c.236A>T p.Q79L | Missense Mutation (SNP) | VAF 44/322 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.284); catalogued as rs566158995; called by muse, mutect2, varscan2
- IGSF8 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs779628536; called by muse, mutect2, varscan2
- IQGAP3 | c.1205G>T p.C402F | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV63255820; called by muse, mutect2
- ISCU | c.445G>T p.A149S (on ENST00000311893 / NM_213595.4; = p.A124S on NM_014301.4) | Missense Mutation (SNP) | VAF 81/343 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs750338671; called by muse, mutect2, varscan2
- ISOC1 | c.439G>T p.A147S | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.663); catalogued as rs767561512; called by muse, mutect2, varscan2
- ITGA10 | c.2369G>T p.G790V | Missense Mutation (SNP) | VAF 47/264 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1553745878; called by muse, mutect2, varscan2
- ITGA2B | c.2075G>T p.R692L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.299); catalogued as COSV99289071; called by muse, mutect2, varscan2
- IWS1 | c.893G>T p.R298L | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV54866962; called by muse, mutect2, varscan2
- KALRN | c.6079C>T p.R2027C (on ENST00000360013 / NM_001024660.4; = p.R330C on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/243 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs149923815; called by muse, mutect2, varscan2
- KCNMB2 | c.704G>A p.R235K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); catalogued as rs760825316; called by muse, mutect2, varscan2
- KCNT2 | c.2747T>C p.L916P | Missense Mutation (SNP) | VAF 14/344 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV54081669; called by muse, mutect2
- KIAA0100 | c.6281C>T p.S2094L | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs756616185; called by muse, mutect2, varscan2
- KIR2DL1 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 77/423 reads (18%) | catalogued as rs750705981, COSV52412543; called by muse, varscan2
- KLHDC2 | c.94C>G p.R32G | Missense Mutation (SNP) | VAF 10/340 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100027056; called by muse, mutect2
- KLHL42 | c.1493A>T p.Y498F | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs1456526390; called by muse, mutect2
- KRT13 | c.1028C>A p.A343E | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV55839888; called by muse, mutect2, varscan2
- KRT78 | c.1111G>T p.A371S | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145610633; called by muse, mutect2, varscan2
- LGI1 | c.611C>A p.P204Q | Missense Mutation (SNP) | VAF 41/245 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.374); catalogued as CD020573, COSV65057947; called by muse, mutect2, varscan2
- LHX2 | c.594C>A p.S198R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.105); catalogued as rs866465572; called by muse, mutect2, varscan2
- LMAN1L | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs780746803, COSV59001804; called by muse, mutect2, varscan2
- LMLN2 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 31/320 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.099); catalogued as rs1238010160; called by muse, mutect2
- LMNB2 | c.1432_1434del p.E478del | In Frame Del (DEL) | VAF 20/118 reads (17%) | catalogued as rs775270360; called by pindel, varscan2
- LPA | c.3865A>G p.T1289A | Missense Mutation (SNP) | VAF 229/510 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99069548; called by muse, mutect2, varscan2
- LPA | c.3530G>A p.R1177Q | Missense Mutation (SNP) | VAF 37/417 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs758209955; called by muse, mutect2
- LRFN5 | c.748T>C p.W250R | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53263064; called by muse, mutect2
- LRP1 | c.5518A>T p.I1840F | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.216); catalogued as COSV54511666; called by muse, mutect2, varscan2
- LRRC43 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.031); catalogued as rs1213602781; called by muse, mutect2, varscan2
- LY75 | c.2666C>T p.S889L | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV99717096; called by muse, mutect2, varscan2
- MAGI2 | c.4328C>T p.P1443L | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs904347487; called by muse, mutect2, varscan2
- MAP2K1 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 69/399 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.934); catalogued as COSV57234979; called by muse, mutect2, varscan2
- MAPT | c.722C>A p.A241D (on ENST00000262410 / NM_001377265.1; = p.A166D on NM_016835.4) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.396); catalogued as COSV99043694; called by muse, mutect2, varscan2
- MAST1 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1377652181, COSV52240739; called by muse, mutect2, varscan2
- MBOAT1 | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375675677; called by muse, mutect2, varscan2
- MCHR2 | c.797del p.P266Lfs*4 | Frame Shift Del (DEL) | VAF 52/367 reads (14%) | catalogued as COSV99912157; called by mutect2, pindel, varscan2
- MFGE8 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 77/266 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1488407396, COSV51555555; called by muse, mutect2, varscan2
- MFN2 | c.1483C>T p.Q495* | Nonsense Mutation (SNP) | VAF 13/141 reads (9%) | catalogued as rs1352495173; called by muse, mutect2, varscan2
- MRGPRG | c.274G>C p.G92R | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60040474; called by muse, mutect2
- MTRF1 | c.1288G>T p.E430* | Nonsense Mutation (SNP) | VAF 87/256 reads (34%) | catalogued as COSV65262792; called by muse, mutect2, varscan2
- MUC12 | c.2296G>T p.G766C (on ENST00000379442; = p.G623C on NM_001164462.1) | Missense Mutation (SNP) | VAF 84/249 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV65192420; called by muse, mutect2, varscan2
- MUC4 | c.6041C>A p.A2014D | Missense Mutation (SNP) | VAF 42/317 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.839); catalogued as rs1560366746; called by muse, mutect2, varscan2
- MYH10 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 81/134 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1326476998; called by muse, mutect2, varscan2
- MYO18B | c.988G>T p.G330C | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV59143205; called by muse, mutect2, varscan2
- MYO5C | c.4080C>G p.Y1360* | Nonsense Mutation (SNP) | VAF 62/231 reads (27%) | catalogued as COSV55911041; called by muse, mutect2, varscan2
- MYO9A | c.7271A>T p.D2424V | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); catalogued as rs1476195374; called by muse, mutect2, varscan2
- MYOM3 | c.2153T>C p.I718T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1422653188; called by muse, mutect2, varscan2
- NAALADL2 | c.886G>T p.V296L | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs763266150, COSV69159800; called by muse, mutect2, varscan2
- NECTIN3 | c.592G>T p.G198* | Nonsense Mutation (SNP) | VAF 172/540 reads (32%) | catalogued as COSV60550392; called by muse, mutect2, varscan2
- NEUROD4 | c.499A>G p.S167G | Missense Mutation (SNP) | VAF 79/375 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs900225265; called by muse, mutect2, varscan2
- NID2 | c.2121G>T p.Q707H | Missense Mutation (SNP) | VAF 122/236 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV99357021; called by muse, mutect2, varscan2
- NLRP5 | c.155T>A p.M52K | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as CM158626; called by muse, mutect2, varscan2
- NLRP5 | c.156G>T p.M52I | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV66765065; called by muse, mutect2, varscan2
- NPAP1 | c.2339C>A p.P780Q | Missense Mutation (SNP) | VAF 88/152 reads (58%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs139282108; called by muse, mutect2, varscan2
- NPHP3 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs200233813, COSV58129388, COSV58130515; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRAP | c.4118A>T p.Q1373L (on ENST00000359988 / NM_001322945.2; = p.Q1338L on NM_006175.4) | Missense Mutation (SNP) | VAF 103/248 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63494247; called by muse, mutect2, varscan2
- NRXN1 | c.2986G>T p.D996Y | Missense Mutation (SNP) | VAF 117/163 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100455497; called by muse, mutect2, varscan2
- NTN3 | c.218G>C p.R73P | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.638); catalogued as rs1369557373; called by muse, mutect2, varscan2
- NYAP1 | c.674G>A p.R225K | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs1177815007; called by muse, mutect2
- OR13C8 | c.861G>A p.M287I | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV58610934, COSV58611937; called by muse, mutect2, varscan2
- OR13F1 | c.416G>T p.R139I | Missense Mutation (SNP) | VAF 109/241 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.824); catalogued as rs774313872; called by muse, mutect2, varscan2
- OR2C3 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 61/295 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as rs200221174; called by muse, mutect2, varscan2
- OR4K17 | c.671C>A p.T224N | Missense Mutation (SNP) | VAF 165/327 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as rs1311596870, COSV100210616; called by muse, mutect2, varscan2
- OR4X2 | c.776T>C p.I259T | Missense Mutation (SNP) | VAF 109/225 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.079); catalogued as rs755393043, COSV56584376; called by muse, mutect2, varscan2
- OR5H15 | c.728C>A p.A243D | Missense Mutation (SNP) | VAF 143/562 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs773253290, COSV100736606, COSV62948324; called by muse, mutect2, varscan2
- OR5L1 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 60/324 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV100450209, COSV61735265; called by muse, mutect2, varscan2
- OR6C1 | c.724C>A p.H242N | Missense Mutation (SNP) | VAF 123/262 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101110531; called by muse, mutect2, varscan2
- OR8B3 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as rs148058485; called by muse, mutect2, varscan2
- OXCT1 | c.1173-3C>T | Splice Region (SNP) | VAF 144/758 reads (19%) | catalogued as rs918891940; called by muse, mutect2, varscan2
- PAX1 | c.421C>A p.R141S | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68272487; called by muse, mutect2, varscan2
- PBX1 | c.1132A>G p.I378V | Missense Mutation (SNP) | VAF 64/378 reads (17%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.013); catalogued as rs775324300; called by muse, mutect2, varscan2
- PCDH15 | c.5677G>A p.E1893K | Missense Mutation (SNP) | VAF 118/778 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57402568; called by muse, varscan2
- PCDH15 | c.2617G>C p.E873Q | Missense Mutation (SNP) | VAF 53/557 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV57310158, COSV57380217; called by muse, mutect2
- PCDH17 | c.3221C>A p.T1074N | Missense Mutation (SNP) | VAF 122/304 reads (40%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV64976473; called by muse, mutect2, varscan2
- PCDHA6 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 92/244 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.137); catalogued as rs781972651, COSV65356990; called by muse, varscan2
- PCDHA9 | c.1935G>C p.Q645H | Missense Mutation (SNP) | VAF 130/244 reads (53%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.019); catalogued as rs1346427061, COSV65331042; called by muse, mutect2, varscan2
- PCDHB2 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs949003962, COSV99523144; called by muse, mutect2, varscan2
- PCDHB5 | c.434G>A p.S145N | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.006); catalogued as rs200919972, COSV50662418; called by muse, mutect2, varscan2
- PCDHGA12 | c.452G>C p.R151P | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.387); catalogued as rs1054638121, COSV52748053, COSV52748059; called by muse, mutect2, varscan2
- PCDHGB3 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.407); catalogued as rs1172687028, COSV53892160, COSV53953403, COSV54003760; called by muse, mutect2, varscan2
- PCLO | c.11462G>T p.R3821L | Missense Mutation (SNP) | VAF 120/268 reads (45%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV61617496; called by muse, mutect2, varscan2
- PCNX2 | c.5190G>T p.E1730D | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50806938; called by muse, mutect2, varscan2
- PCOLCE2 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 21/78 reads (27%) | catalogued as COSV56000166, COSV99930940; called by muse, mutect2
- PDE1C | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 103/296 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV100371920; called by muse, mutect2, varscan2
- PDE6G | c.6C>A p.N2K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as rs766951952; called by muse, mutect2, varscan2
- PGK2 | c.925C>A p.P309T | Missense Mutation (SNP) | VAF 159/265 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV59165964; called by muse, mutect2, varscan2
- PHLDB2 | c.1769T>C p.M590T | Missense Mutation (SNP) | VAF 55/655 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs1476753068; called by muse, mutect2
- PIK3R4 | c.2365G>T p.A789S | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs1359465095; called by muse, mutect2, varscan2
- PITPNM1 | c.2843C>T p.T948M | Missense Mutation (SNP) | VAF 235/337 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751785595; called by muse, mutect2, varscan2
- PIWIL4 | c.152G>T p.R51M | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as COSV54409716; called by muse, mutect2, varscan2
- PKHD1 | c.11932C>T p.H3978Y | Missense Mutation (SNP) | VAF 76/128 reads (59%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.044); catalogued as rs547782981; called by muse, mutect2, varscan2
- PLPPR4 | c.1253C>A p.P418Q | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100926975; called by muse, mutect2, varscan2
- POMT1 | c.586G>C p.A196P | Missense Mutation (SNP) | VAF 174/336 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.902); catalogued as COSV100586601; called by muse, mutect2, varscan2
- PPFIA2 | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as rs750703254; called by muse, mutect2
- PPP1R3A | c.1670C>G p.A557G | Missense Mutation (SNP) | VAF 127/306 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.172); catalogued as COSV99492149; called by muse, mutect2, varscan2
- PRAMEF27 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1174375626; called by muse, mutect2, varscan2
- PREP | c.961G>A p.G321S (on ENST00000369110; = p.G387S on NM_002726.5) | Missense Mutation (SNP) | VAF 35/369 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.408); catalogued as rs752657011; called by muse, mutect2
- PRKG1 | c.983G>T p.C328F | Missense Mutation (SNP) | VAF 116/308 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100907190; called by muse, mutect2, varscan2
- PRRT1 | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 65/122 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52997671; called by muse, mutect2, varscan2
- PSCA | c.132C>G p.I44M | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs782240163; called by muse, mutect2, varscan2
- PSCA | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs782393686, COSV56652241; called by muse, mutect2, varscan2
- PTPRD | c.5242G>T p.E1748* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV61961009; called by muse, mutect2, varscan2
- PTPRH | c.2153T>C p.V718A | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1204420433; called by muse, mutect2, varscan2
- PTPRT | c.3725A>G p.Q1242R | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.595); catalogued as rs1239953098; called by muse, mutect2, varscan2
- PZP | c.4056G>T p.Q1352H | Missense Mutation (SNP) | VAF 65/530 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs767544910; called by muse, mutect2, varscan2
- PZP | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs1282229854; called by muse, mutect2, varscan2
- RANBP9 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 181/371 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1029630802, COSV99163648; called by muse, mutect2, varscan2
- RASGRP3 | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.109); catalogued as COSV67823549; called by muse, mutect2
- RBM47 | c.1489G>A p.A497T (on ENST00000295971 / NM_001098634.2; = p.A428T on NM_019027.4) | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs780492136, COSV55931341; called by muse, mutect2, varscan2
- RDH16 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.182); catalogued as COSV100660072; called by muse, mutect2, varscan2
- RELN | c.6607C>A p.L2203I | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1296074586; called by muse, mutect2, varscan2
- REN | c.1206C>G p.F402L | Missense Mutation (SNP) | VAF 70/261 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.801); catalogued as COSV65817392; called by muse, mutect2, varscan2
- RGS7 | c.1247G>T p.R416L | Missense Mutation (SNP) | VAF 88/453 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100464246, COSV58537660; called by muse, mutect2, varscan2
- RIPPLY2 | c.229C>A p.H77N | Missense Mutation (SNP) | VAF 41/299 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63762732; called by muse, mutect2, varscan2
- RNF112 | c.1320G>T p.R440S | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV71327087; called by muse, mutect2, varscan2
- RNGTT | c.1745C>T p.T582M | Missense Mutation (SNP) | VAF 38/403 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs370993760, COSV55646826; called by muse, mutect2, varscan2
- RP1L1 | c.2792G>T p.G931V | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs763665045, COSV66754723; called by muse, mutect2, varscan2
- RSPH6A | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760746284; called by muse, mutect2, varscan2
- RYR1 | c.2425C>A p.P809T | Missense Mutation (SNP) | VAF 167/373 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62089014; called by muse, mutect2, varscan2
- RYR2 | c.11854G>T p.A3952S | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.951); catalogued as COSV63721939; called by muse, mutect2, varscan2
- SAMD7 | c.367G>T p.G123W | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV59418780, COSV59419692; called by muse, mutect2, varscan2
- SCN11A | c.2009G>A p.R670H | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs199807325; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN3A | c.3256G>T p.D1086Y | Missense Mutation (SNP) | VAF 39/321 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs149911613; called by muse, mutect2, varscan2
- SEMA3E | c.781G>C p.A261P | Missense Mutation (SNP) | VAF 202/544 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs773917768, COSV57103792; called by muse, mutect2, varscan2
- SEMG2 | c.1471C>A p.Q491K | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101033986; called by muse, mutect2, varscan2
- SERPINA3 | c.1022C>A p.A341D | Missense Mutation (SNP) | VAF 184/335 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1215229472; called by muse, mutect2, varscan2
- SERPINA5 | c.705G>C p.M235I | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs776122878; called by muse, mutect2, varscan2
- SERPINE1 | c.100C>A p.L34M | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as COSV56170815, COSV56171791; called by muse, mutect2, varscan2
- SGCG | c.337G>C p.V113L | Missense Mutation (SNP) | VAF 74/335 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV54563101; called by muse, mutect2, varscan2
- SH3PXD2B | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as rs776418736; called by muse, mutect2, varscan2
- SHPRH | c.3568C>T p.Q1190* (on ENST00000275233 / NM_001042683.3; = p.Q1194* on NM_173082.3) | Nonsense Mutation (SNP) | VAF 16/182 reads (9%) | catalogued as rs1244331956; called by muse, mutect2
- SIAH2 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs1000092748; called by muse, mutect2, varscan2
- SIRT6 | c.653A>T p.Q218L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99314165; called by muse, mutect2, varscan2
- SLC10A2 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 84/382 reads (22%) | catalogued as COSV55361015, COSV55362212; called by muse, mutect2, varscan2
- SLC13A3 | c.864G>T p.L288F | Missense Mutation (SNP) | VAF 37/255 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs1413101043; called by muse, mutect2, varscan2
- SLC17A9 | c.399G>T p.G133= | Splice Region (SNP) | VAF 28/84 reads (33%) | catalogued as rs1265774222; called by muse, mutect2, varscan2
- SLC25A39 | c.638G>T p.R213L (on ENST00000377095 / NM_001143780.3; = p.R205L on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs745986185, COSV99835057; called by mutect2, varscan2
- SLC28A1 | c.163G>T p.A55S | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs113577701; called by muse, mutect2, varscan2
- SLC40A1 | c.1378G>T p.A460S | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.068); catalogued as rs1199163446; called by muse, mutect2, varscan2
- SMARCA4 | c.3479G>T p.G1160V | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60798133, COSV60813326; called by muse, mutect2, varscan2
- SMG8 | c.2120G>T p.G707V | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs1255706272; called by muse, mutect2, varscan2
- SMPDL3A | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 61/313 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as COSV99054979; called by muse, mutect2, varscan2
- SMPDL3A | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100868708; called by muse, mutect2, varscan2
- SNCA | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 111/384 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261963254; called by muse, mutect2, varscan2
- SORBS2 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 88/253 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1031340076; called by muse, mutect2, varscan2
- SORCS3 | c.2115C>A p.H705Q | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.041); catalogued as COSV63798027; called by muse, mutect2, varscan2
- SPATA18 | c.1221C>A p.F407L | Missense Mutation (SNP) | VAF 186/309 reads (60%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1010080376; called by muse, mutect2, varscan2
- SSC5D | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); catalogued as rs1007625075; called by muse, mutect2, varscan2
- STXBP2 | c.1574G>T p.G525V | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as COSV55405699; called by muse, mutect2, varscan2
- TAF4 | c.2057C>G p.T686S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.85); PolyPhen benign (0.241); catalogued as COSV53338636; called by muse, mutect2, varscan2
- TBC1D21 | c.790G>T p.G264W | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55995450; called by muse, mutect2
- TBX22 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 95/188 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.058); catalogued as rs1363320972; called by muse, mutect2, varscan2
- TCERG1L | c.612G>T p.R204S | Missense Mutation (SNP) | VAF 73/243 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV64047539; called by muse, mutect2, varscan2
- TDRD1 | c.2283C>A p.F761L | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV99313962; called by muse, mutect2, varscan2
- TGM1 | c.908A>G p.Y303C | Missense Mutation (SNP) | VAF 175/292 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs757256224; called by muse, mutect2, varscan2
- TGM4 | c.727C>A p.P243T | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149567908; called by muse, mutect2
- THEMIS | c.904C>A p.Q302K | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV64069004; called by muse, varscan2
- THEMIS | c.892del p.Q298Kfs*11 | Frame Shift Del (DEL) | VAF 18/119 reads (15%) | catalogued as COSV64070811; called by pindel, varscan2
- TMEM132C | c.1025C>A p.P342H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1326689389; called by muse, varscan2
- TMPRSS11F | c.1175C>A p.P392H | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62466443; called by muse, mutect2, varscan2
- TMPRSS6 | c.1210C>A p.R404S | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV60980957; called by muse, varscan2
- TNRC6B | c.5233G>T p.G1745W (on ENST00000454349 / NM_001162501.2; = p.G1635W on NM_015088.3) | Missense Mutation (SNP) | VAF 86/317 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1427240135; called by muse, mutect2, varscan2
- TNXB | c.6014C>T p.T2005I (on ENST00000647633; = p.T1758I on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.484); catalogued as rs1279482319; called by muse, mutect2, varscan2
- TONSL | c.3721C>T p.R1241* | Nonsense Mutation (SNP) | VAF 10/78 reads (13%) | catalogued as rs782512578; called by mutect2, varscan2
- TPBGL | c.544A>C p.N182H | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1441943213; called by muse, mutect2, varscan2
- TPO | c.1247G>T p.R416L | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs996193341; called by muse, mutect2, varscan2
- TRIM58 | c.1334G>T p.R445L | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV100825132, COSV63569813; called by muse, mutect2, varscan2
- TRIM63 | c.598-1G>T p.X200_splice | Splice Site (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100958164; called by muse, mutect2, varscan2
- TRIOBP | c.6161G>T p.R2054L (on ENST00000644935 / NM_001039141.3; = p.R341L on NM_007032.5) | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs765284417; called by muse, mutect2, varscan2
- TRMT1 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.29); catalogued as rs751482306; called by mutect2, varscan2
- TRPS1 | c.1549G>T p.D517Y (on ENST00000220888 / NM_001330599.2; = p.D530Y on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/478 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.525); catalogued as COSV55254348; called by muse, mutect2, varscan2
- TRPV5 | c.308C>A p.P103Q | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54683323; called by muse, mutect2, varscan2
- TTN | c.14273C>T p.P4758L (on ENST00000591111; = p.P3831L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | PolyPhen probably damaging (0.999); catalogued as rs1553929816, COSV60295848; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TXLNB | c.1907C>G p.A636G | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.01); catalogued as COSV100624990; called by muse, mutect2, varscan2
- UBR3 | c.4423G>T p.A1475S | Missense Mutation (SNP) | VAF 107/255 reads (42%) | SIFT tolerated (0.77); PolyPhen benign (0.052); catalogued as COSV55855267; called by muse, mutect2, varscan2
- UGT2A1 | c.293G>A p.R98K | Missense Mutation (SNP) | VAF 87/189 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.024); catalogued as COSV99683667; called by muse, mutect2, varscan2
- UNC5B | c.2485G>A p.A829T | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.205); catalogued as rs1046581208; called by muse, mutect2
- UNKL | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as rs574875280, COSV100061514; called by muse, mutect2, varscan2
- USH2A | c.9054G>T p.G3018= | Splice Region (SNP) | VAF 155/582 reads (27%) | catalogued as COSV56338987; called by muse, mutect2, varscan2
- VAT1 | c.622C>A p.L208M | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV55897122; called by muse, mutect2, varscan2
- VCAN | c.7055C>T p.S2352F | Missense Mutation (SNP) | VAF 45/358 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as rs1320409064; called by muse, mutect2, varscan2
- VN1R2 | c.131C>A p.A44D | Missense Mutation (SNP) | VAF 37/149 reads (25%) | PolyPhen possibly damaging (0.665); catalogued as rs1212789531; called by muse, mutect2, varscan2
- VPS13C | c.3029G>T p.G1010V (on ENST00000644861 / NM_020821.3; = p.G967V on NM_017684.5) | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV51278783; called by muse, mutect2, varscan2
- VPS13C | c.3028G>C p.G1010R (on ENST00000644861 / NM_020821.3; = p.G967R on NM_017684.5) | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as rs1406593183; called by muse, mutect2, varscan2
- VPS13D | c.2953G>A p.A985T | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as rs763987782; called by muse, mutect2, varscan2
- VSTM1 | c.602C>A p.P201H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs144710636; called by muse, mutect2, varscan2
- WSCD1 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV100496556; called by muse, mutect2, varscan2
- WTIP | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 17/99 reads (17%) | catalogued as rs1254261696; called by muse, mutect2, varscan2
- XIRP2 | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 125/252 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.038); catalogued as rs942815960; called by muse, mutect2, varscan2
- XKR9 | c.56T>C p.V19A | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as COSV68773320; called by muse, mutect2, varscan2
- YME1L1 | c.502G>T p.G168C (on ENST00000326799 / NM_139312.3; = p.G111C on NM_014263.4) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58761110; called by muse, mutect2
- YTHDF1 | c.29G>T p.R10I | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV64834964; called by muse, mutect2, varscan2
- ZBBX | c.57G>T p.K19N | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56786751; called by muse, mutect2, varscan2
- ZNF267 | c.1985G>A p.C662Y | Missense Mutation (SNP) | VAF 136/494 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138496836; called by muse, mutect2, varscan2
- ZNF502 | c.987del p.T331Lfs*124 | Frame Shift Del (DEL) | VAF 24/75 reads (32%) | catalogued as COSV99939756; called by mutect2, pindel, varscan2
- ZNF536 | c.2660G>T p.G887V | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs775309484; called by muse, mutect2, varscan2
- ZNF629 | c.1390G>A p.G464S | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52700867; called by muse, mutect2
- ZNF679 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs779462779; called by muse, mutect2
- ZNF804A | c.1276G>T p.V426L | Missense Mutation (SNP) | VAF 71/206 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV56456895, COSV56462599; called by muse, mutect2, varscan2
- ZNF808 | c.1112A>T p.Y371F | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV63120291; called by muse, mutect2, varscan2
- ZYX | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 78/173 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as COSV59557274; called by muse, mutect2, varscan2
- AASS | c.477G>T p.M159I | Missense Mutation (SNP) | VAF 194/529 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ABCC9 | c.2630C>G p.T877R | Missense Mutation (SNP) | VAF 43/521 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.07); called by muse, mutect2
- ABCF3 | c.1408G>T p.V470L | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ABHD3 | c.904A>G p.R302G | Missense Mutation (SNP) | VAF 126/281 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- ABL2 | c.1520C>A p.P507H (on ENST00000502732 / NM_007314.4; = p.P492H on NM_005158.5) | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AC013489.1 | c.661G>T p.G221W | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC024940.1 | n.4595A>G | Splice Region (SNP) | VAF 162/492 reads (33%) | called by muse, mutect2, varscan2
- AC090517.4 | c.144G>C p.L48F | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC127029.3 | c.826C>A p.L276I | Missense Mutation (SNP) | VAF 79/312 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ACAD10 | c.2818G>A p.V940M | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ACSM2A | c.105G>T p.W35C | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ACSM6 | c.30G>T p.L10F | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.262); called by muse, mutect2
- ACTN2 | c.1229C>G p.A410G | Missense Mutation (SNP) | VAF 92/408 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ADAMTS13 | c.509G>A p.G170D | Missense Mutation (SNP) | VAF 85/227 reads (37%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- ADAMTS14 | c.1214G>A p.G405D | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRG4 | c.620G>T p.S207I | Missense Mutation (SNP) | VAF 62/93 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- AFAP1 | c.1835A>T p.E612V | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, varscan2
- AFF2 | c.334C>A p.P112T | Missense Mutation (SNP) | VAF 70/141 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AFF2 | c.3727G>C p.A1243P | Missense Mutation (SNP) | VAF 7/188 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AFF3 | c.1171G>T p.A391S | Missense Mutation (SNP) | VAF 89/297 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- AGBL4 | c.337G>T p.G113W | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGMO | c.787C>A p.H263N | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.269); called by muse, mutect2
- AHNAK2 | c.13432C>T p.P4478S | Missense Mutation (SNP) | VAF 122/195 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AKAP6 | c.4608G>A p.M1536I | Missense Mutation (SNP) | VAF 36/662 reads (5%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.006); called by muse, mutect2
- AKAP9 | c.5132A>T p.D1711V | Missense Mutation (SNP) | VAF 38/331 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ALDH1L1 | c.2355_2357del p.F786del | In Frame Del (DEL) | VAF 16/124 reads (13%) | called by pindel, varscan2
- ALG5 | c.705G>T p.Q235H | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMPD1 | c.2004G>T p.L668F | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- ANK2 | c.2549-1G>T p.X850_splice | Splice Site (SNP) | VAF 56/200 reads (28%) | called by muse, mutect2, varscan2
- ANK2 | c.11764G>T p.G3922* | Nonsense Mutation (SNP) | VAF 100/319 reads (31%) | called by muse, mutect2, varscan2
- ANO9 | c.589T>C p.Y197H | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ANOS1 | c.757A>T p.I253L | Missense Mutation (SNP) | VAF 105/206 reads (51%) | SIFT tolerated (0.43); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- AP002512.3 | c.1157C>A p.P386H | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP3B2 | c.3034C>G p.R1012G (on ENST00000261722; = p.R1006G on NM_004644.5) | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- APCDD1L | c.682C>A p.P228T | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.015); called by muse, mutect2
- AR | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ARHGAP31 | c.3111del p.I1038Sfs*3 | Frame Shift Del (DEL) | VAF 54/163 reads (33%) | called by mutect2, pindel, varscan2
- ARHGEF10 | c.698-1G>T p.X233_splice (on ENST00000398564; = p.X208_splice on NM_014629.4) | Splice Site (SNP) | VAF 31/345 reads (9%) | called by muse, mutect2
- ARHGEF17 | c.3722A>T p.Q1241L | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ARHGEF9 | c.972G>T p.E324D | Missense Mutation (SNP) | VAF 76/131 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ARID4A | c.193A>T p.I65F | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ARPP21 | c.1637T>C p.V546A | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.087); called by muse, varscan2
- ARPP21 | c.2227C>A p.Q743K | Missense Mutation (SNP) | VAF 96/213 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ASCC3 | c.2127G>T p.L709F | Missense Mutation (SNP) | VAF 172/474 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ASPH | c.1732C>T p.P578S | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- ASZ1 | c.1342A>T p.S448C | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ATAD3B | c.460G>C p.G154R (on ENST00000308647; = p.G260R on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATF6 | c.81G>T p.W27C | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATF7IP | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 25/102 reads (25%) | called by muse, mutect2, varscan2
- ATG13 | c.903G>T p.L301= (on ENST00000359513 / NM_001346321.1; = p.L264= on NM_014741.4 and 9 other RefSeq transcripts) | Splice Region (SNP) | VAF 26/48 reads (54%) | called by muse, mutect2, varscan2
- ATG9B | c.2415G>T p.Q805H | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP1B3 | c.32A>G p.Q11R | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ATXN2 | c.976G>T p.E326* (on ENST00000550104; = p.E166* on NM_002973.4) | Nonsense Mutation (SNP) | VAF 33/181 reads (18%) | called by muse, mutect2, varscan2
- AURKC | c.189G>C p.K63N (on ENST00000302804 / NM_001015878.2; = p.K29N on NM_003160.3) | Missense Mutation (SNP) | VAF 80/323 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- AUTS2 | c.1304T>G p.L435R | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- B3GAT2 | c.359C>A p.A120E | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BCAN | c.1316T>A p.M439K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- BMS1 | c.1820C>G p.S607* | Nonsense Mutation (SNP) | VAF 19/167 reads (11%) | called by muse, mutect2, varscan2
- BPIFB6 | c.405G>C p.E135D | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- BRD9 | c.302G>T p.C101F | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- C10orf67 | c.787C>A p.L263I | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- C10orf71 | c.1397A>T p.E466V | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.173); called by muse, mutect2
- C10orf90 | c.1573G>C p.E525Q | Missense Mutation (SNP) | VAF 105/212 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- C12orf75 | c.115G>T p.G39* | Nonsense Mutation (SNP) | VAF 17/144 reads (12%) | called by muse, mutect2, varscan2
- C19orf81 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C1QB | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- C20orf85 | c.410A>T p.H137L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.124); called by mutect2, varscan2
- C3orf38 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 54/366 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, varscan2
- C7 | c.1864G>T p.G622W | Missense Mutation (SNP) | VAF 226/529 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C9orf43 | c.891G>T p.Q297H | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CACNA1B | c.2603G>T p.R868L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CACNA1B | c.5896G>T p.G1966W | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CACNA1S | c.2623G>T p.V875L | Missense Mutation (SNP) | VAF 87/326 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- CACNG1 | c.357C>G p.I119M | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CADPS2 | c.641A>T p.E214V | Missense Mutation (SNP) | VAF 61/551 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- CALY | c.135G>T p.Q45H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CAP1 | c.779A>C p.Q260P | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- CARD11 | c.2759G>A p.R920H | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); called by muse, varscan2
- CARD6 | c.2033C>A p.T678K | Missense Mutation (SNP) | VAF 158/352 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CASP5 | c.247G>T p.V83F | Missense Mutation (SNP) | VAF 114/306 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CATSPERG | c.2518A>T p.S840C | Missense Mutation (SNP) | VAF 90/161 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CBFA2T3 | c.34A>T p.S12C | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CBLN3 | c.122T>A p.L41Q | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC154 | c.1800G>T p.K600N | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- CCDC158 | c.2596C>G p.P866A | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CCDC168 | c.19065del p.N6357Ifs*2 | Frame Shift Del (DEL) | VAF 26/179 reads (15%) | called by mutect2, pindel, varscan2
- CCDC3 | c.537G>T p.Q179H | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); called by muse, mutect2
- CCT5 | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 42/526 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.013); called by muse, mutect2
- CD22 | c.1505A>G p.Q502R | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.021); called by muse, mutect2
- CD276 | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDH22 | c.1711G>T p.E571* | Nonsense Mutation (SNP) | VAF 45/102 reads (44%) | called by muse, mutect2, varscan2
- CDK6 | c.157G>C p.G53R | Missense Mutation (SNP) | VAF 128/323 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEACAM8 | c.768C>A p.N256K | Missense Mutation (SNP) | VAF 150/268 reads (56%) | SIFT tolerated (0.32); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- CELSR1 | c.1958A>G p.Y653C | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELSR2 | c.5551del p.H1851Mfs*121 | Frame Shift Del (DEL) | VAF 48/190 reads (25%) | called by mutect2, pindel, varscan2
- CEND1 | c.407T>C p.I136T | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.04); called by muse, mutect2
- CENPT | c.1248_1265del p.F416_A422delinsL | In Frame Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel, varscan2
- CFAP100 | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- CFAP58 | c.1824T>G p.S608R | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.005); called by muse, varscan2
- CFAP74 | c.3308C>T p.A1103V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- CHIT1 | c.667G>T p.G223* | Nonsense Mutation (SNP) | VAF 97/328 reads (30%) | called by muse, mutect2, varscan2
- CHL1 | c.97C>A p.Q33K | Missense Mutation (SNP) | VAF 83/145 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CHRM2 | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 63/545 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.542); called by muse, varscan2
- CHST1 | c.203C>A p.T68N | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- CHTF18 | c.2534C>G p.A845G | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CIC | c.1372T>C p.F458L | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.351); called by muse, mutect2
- CKAP2L | c.1533G>T p.K511N | Missense Mutation (SNP) | VAF 77/310 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- CLEC1B | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 231/758 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLEC9A | c.649A>T p.N217Y | Missense Mutation (SNP) | VAF 174/360 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CMYA5 | c.2544G>T p.L848F | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CMYA5 | c.3775G>T p.V1259F | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- CNKSR2 | c.287C>A p.A96D | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CNNM1 | c.1276A>C p.T426P | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CNOT6 | c.312A>C p.L104F | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTN2 | c.684C>A p.N228K | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.93); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- CNTNAP2 | c.593A>G p.Y198C | Missense Mutation (SNP) | VAF 57/395 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CNTNAP2 | c.3409del p.H1137Ifs*22 | Frame Shift Del (DEL) | VAF 44/427 reads (10%) | called by mutect2, pindel, varscan2
- CNTNAP2 | c.3915G>T p.E1305D | Missense Mutation (SNP) | VAF 117/284 reads (41%) | SIFT tolerated (0.9); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- COBL | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.006); called by mutect2, varscan2
- COL11A1 | c.2710G>T p.G904C | Missense Mutation (SNP) | VAF 127/524 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL12A1 | c.8384G>T p.G2795V | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL12A1 | c.7573G>T p.E2525* | Nonsense Mutation (SNP) | VAF 32/169 reads (19%) | called by muse, mutect2, varscan2
- COL20A1 | c.592G>C p.V198L | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- COL24A1 | c.2606T>A p.I869N | Missense Mutation (SNP) | VAF 74/326 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- COL3A1 | c.529-1G>T p.X177_splice | Splice Site (SNP) | VAF 156/524 reads (30%) | called by muse, mutect2, varscan2
- COL4A3 | c.3761G>A p.G1254D | Missense Mutation (SNP) | VAF 48/239 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRAT | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- CRHBP | c.357G>T p.K119N | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRIP3 | c.619C>A p.L207M | Missense Mutation (SNP) | VAF 26/32 reads (81%) | PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CRISP2 | c.228C>A p.N76K | Missense Mutation (SNP) | VAF 197/386 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- CRYBG2 | c.3439C>A p.P1147T | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.295); called by muse, mutect2
- CSMD3 | c.10891G>T p.V3631L (on ENST00000297405 / NM_001363185.1; = p.V3462L on NM_052900.3) | Missense Mutation (SNP) | VAF 135/382 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CST1 | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 51/86 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- CTAGE1 | c.1892G>T p.S631I | Missense Mutation (SNP) | VAF 172/402 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); called by muse, varscan2
- CUBN | c.8904A>T p.E2968D | Missense Mutation (SNP) | VAF 36/337 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- CUX2 | c.777G>T p.E259D | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CUX2 | c.1747C>A p.L583M | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP2C18 | c.146A>T p.D49V | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- CYP2C18 | c.207T>G p.F69L | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CYP4B1 | c.763G>T p.D255Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- CYP4F2 | c.1237G>C p.V413L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- CYP7B1 | c.554G>T p.S185I | Missense Mutation (SNP) | VAF 50/444 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DCAF11 | c.411G>C p.Q137H | Missense Mutation (SNP) | VAF 61/109 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCAF13 | c.696G>C p.L232F | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- DDX46 | c.537G>T p.M179I | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX60L | c.1030T>G p.L344V | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- DEGS1 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 66/289 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- DELE1 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- DENND6A | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- DERA | c.565A>G p.T189A | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.146); called by muse, mutect2
- DHX38 | c.1760G>C p.R587P | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DIAPH3 | c.2851A>G p.T951A (on ENST00000400324 / NM_001042517.2; = p.T688A on NM_030932.3) | Missense Mutation (SNP) | VAF 42/426 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.026); called by muse, mutect2
- DLG4 | c.1858G>T p.A620S (on ENST00000399506 / NM_001321075.3; = p.A663S on NM_001365.4) | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- DLGAP3 | c.1592C>A p.P531H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- DNAAF1 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 36/299 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH10 | c.1529G>T p.R510M (on ENST00000409039; = p.R449M on NM_207437.3) | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- DNAH10 | c.3925A>T p.I1309F (on ENST00000409039; = p.I1248F on NM_207437.3) | Missense Mutation (SNP) | VAF 75/236 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- DNASE2 | c.949G>T p.G317* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
- DNTT | c.770G>T p.G257V | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DOCK8 | c.1484C>G p.S495* | Nonsense Mutation (SNP) | VAF 11/277 reads (4%) | called by muse, mutect2
- DPP6 | c.455G>C p.S152T (on ENST00000377770 / NM_001364500.2; = p.S90T on NM_001936.5) | Missense Mutation (SNP) | VAF 114/272 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, varscan2
- DPP6 | c.1467G>T p.K489N (on ENST00000377770 / NM_001364500.2; = p.K427N on NM_001936.5) | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- DPY19L3 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DPYS | c.883C>T p.H295Y | Missense Mutation (SNP) | VAF 238/478 reads (50%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DSCAM | c.3514G>A p.G1172R | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DSG1 | c.2684C>A p.T895K | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DST | c.9503G>T p.C3168F | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DTNB | c.1085A>T p.Q362L | Missense Mutation (SNP) | VAF 160/212 reads (75%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DUS1L | c.616T>G p.F206V | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- DZANK1 | c.826C>G p.L276V (on ENST00000262547 / NM_001099407.1; = p.L77V on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 193/368 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- EBF3 | c.1286C>A p.P429H (on ENST00000355311 / NM_001375392.1; = p.P420H on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); called by muse, varscan2
- EDIL3 | c.1141G>C p.D381H | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- EEF1AKMT4-ECE2 | c.701C>A p.P234H | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EEPD1 | c.1216G>T p.A406S | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EFHD2 | c.244C>G p.P82A | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- EIF3A | c.3779G>T p.R1260I | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- EIF3A | c.3777G>T p.W1259C | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- EML4 | c.1910A>C p.H637P | Missense Mutation (SNP) | VAF 77/327 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ENPP3 | c.957G>T p.M319I | Missense Mutation (SNP) | VAF 81/212 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENTPD1 | c.848T>C p.F283S | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPB41L3 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHA5 | c.3037G>T p.V1013F | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- EPHA8 | c.2952C>G p.I984M | Missense Mutation (SNP) | VAF 62/181 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHB1 | c.723C>A p.N241K | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ERC2 | c.1159A>T p.I387F | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ERICH6B | c.1666C>A p.L556M | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERN2 | c.379+2T>G p.X127_splice | Splice Site (SNP) | VAF 43/145 reads (30%) | called by muse, mutect2, varscan2
- ERVV-1 | c.895G>T p.G299* | Nonsense Mutation (SNP) | VAF 41/250 reads (16%) | called by muse, mutect2, varscan2
- ESR2 | c.116G>A p.S39N | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.006); called by muse, mutect2
- ESRRG | c.917T>A p.M306K | Missense Mutation (SNP) | VAF 92/495 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EXTL1 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EYS | c.4304A>C p.D1435A | Missense Mutation (SNP) | VAF 56/283 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EYS | c.2242T>A p.C748S | Missense Mutation (SNP) | VAF 40/365 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- F5 | c.1637C>G p.A546G | Missense Mutation (SNP) | VAF 105/614 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- FAM183A | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FAM216B | c.221-1G>T p.X74_splice | Splice Site (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- FAM71F2 | c.64G>A p.V22M | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FBXO15 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FCRL5 | c.119T>G p.V40G | Missense Mutation (SNP) | VAF 29/338 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- FGD5 | c.1578G>T p.L526F | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.13); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- FGF14 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 79/515 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FLG | c.4087C>G p.Q1363E | Missense Mutation (SNP) | VAF 191/694 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- FLG2 | c.2414C>T p.T805I | Missense Mutation (SNP) | VAF 153/601 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- FLNA | c.4687A>T p.S1563C | Missense Mutation (SNP) | VAF 85/138 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FLNC | c.6513G>T p.Q2171H | Missense Mutation (SNP) | VAF 35/242 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- FLVCR1 | c.1421G>A p.G474E | Missense Mutation (SNP) | VAF 53/284 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMO1 | c.350C>A p.S117* | Nonsense Mutation (SNP) | VAF 90/235 reads (38%) | called by muse, mutect2, varscan2
- FOLH1 | c.1148T>C p.F383S | Missense Mutation (SNP) | VAF 65/344 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXP1 | c.1470G>T p.E490D | Missense Mutation (SNP) | VAF 59/239 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FRG1 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 105/362 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FRMD4B | c.731+1G>T p.X244_splice | Splice Site (SNP) | VAF 51/124 reads (41%) | called by muse, mutect2, varscan2
- FRMPD2 | c.3537+1G>T p.X1179_splice | Splice Site (SNP) | VAF 30/424 reads (7%) | called by muse, mutect2
- FRY | c.2547A>T p.K849N | Missense Mutation (SNP) | VAF 58/322 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- FSIP2 | c.8545A>G p.N2849D | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- FSIP2 | c.18418C>T p.P6140S | Missense Mutation (SNP) | VAF 93/251 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- GABRD | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GALNT13 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); called by muse, mutect2
- GBP2 | c.1664A>G p.Q555R | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- GBP7 | c.1066C>A p.H356N | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GCGR | c.265C>A p.H89N | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GDA | c.1144C>A p.L382M | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- GIMAP1 | c.233T>A p.V78E | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GLYR1 | c.881C>A p.T294N | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- GPC6 | c.878A>T p.D293V | Missense Mutation (SNP) | VAF 56/203 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GPHN | c.817G>T p.A273S (on ENST00000315266 / NM_001377519.1; = p.A306S on NM_020806.5) | Missense Mutation (SNP) | VAF 56/430 reads (13%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- GPR15 | c.57C>A p.N19K | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GPR6 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 109/224 reads (49%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- GRIA2 | c.609G>T p.K203N | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GRID1 | c.1380del p.K461Sfs*8 | Frame Shift Del (DEL) | VAF 19/164 reads (12%) | called by mutect2, pindel, varscan2
- GRM5 | c.1322T>C p.L441P | Missense Mutation (SNP) | VAF 174/383 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GSTM3 | c.617A>T p.Q206L | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, varscan2
- GTF2E1 | c.1012G>T p.G338C | Missense Mutation (SNP) | VAF 112/312 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- GTF2IRD2B | c.2040G>T p.W680C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by mutect2, varscan2
- GTF3C4 | c.1177G>T p.A393S | Missense Mutation (SNP) | VAF 76/152 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HAO2 | c.987del p.M330Wfs*102 | Frame Shift Del (DEL) | VAF 24/187 reads (13%) | called by mutect2, pindel, varscan2
- HBS1L | c.1628G>T p.W543L | Missense Mutation (SNP) | VAF 36/478 reads (8%) | SIFT tolerated (0.65); PolyPhen probably damaging (1); called by muse, mutect2
- HDAC6 | c.2078G>T p.R693L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.7); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HEPH | c.1657C>A p.L553M (on ENST00000343002; = p.L286M on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/152 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMBS | c.330C>G p.I110M | Missense Mutation (SNP) | VAF 43/271 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMCN2 | c.9137C>A p.P3046H | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- HOXA10 | c.959G>C p.G320A | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- HOXA9 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- HR | c.3257G>T p.G1086V | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSF5 | c.1334G>T p.G445V | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HSF5 | c.1333G>T p.G445* | Nonsense Mutation (SNP) | VAF 34/143 reads (24%) | called by muse, mutect2, varscan2
- HTR2C | c.1026C>A p.N342K | Missense Mutation (SNP) | VAF 115/233 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- HTR2C | c.1027C>A p.Q343K | Missense Mutation (SNP) | VAF 113/232 reads (49%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- ICA1 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- IFI16 | c.1247A>C p.E416A | Missense Mutation (SNP) | VAF 100/353 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IFI44 | c.676G>T p.G226W | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- IFNA1 | c.241C>A p.H81N | Missense Mutation (SNP) | VAF 42/236 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); called by muse, varscan2
- IFRD1 | c.794A>T p.E265V | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2
- IGHG3 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 112/178 reads (63%) | called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.208G>T p.V70L | Missense Mutation (SNP) | VAF 181/352 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 28/700 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); called by muse, mutect2
- IGHV2OR16-5 | c.17C>A p.S6Y | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by mutect2, varscan2
- IGHV3-49 | c.79G>T p.G27W | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- IGSF1 | c.3976C>T p.Q1326* | Nonsense Mutation (SNP) | VAF 40/74 reads (54%) | called by muse, mutect2, varscan2
- IL16 | c.3584C>G p.T1195R (on ENST00000302987 / NM_172217.5; = p.T494R on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.845); called by muse, mutect2
- IL1A | c.448C>A p.Q150K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.89); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IMMP2L | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- IQCF3 | c.190C>A p.Q64K | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IRAK4 | c.257A>G p.D86G | Missense Mutation (SNP) | VAF 68/292 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- ISM2 | c.1405C>A p.Q469K | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.9); PolyPhen benign (0.01); called by muse, mutect2
- ITGAD | c.1916G>T p.W639L | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ITIH3 | c.1407C>A p.N469K | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ITIH6 | c.334C>T p.Q112* | Nonsense Mutation (SNP) | VAF 32/123 reads (26%) | called by muse, mutect2, varscan2
- IZUMO2 | c.481A>C p.K161Q | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- JSRP1 | c.983A>T p.K328M | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- KALRN | c.284C>G p.T95S | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- KANSL1L | c.2095G>C p.E699Q | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KATNIP | c.1351G>A p.V451M | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- KCNA5 | c.946C>A p.L316M | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KCNC3 | c.936T>G p.H312Q | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCND2 | c.1817C>A p.T606N | Missense Mutation (SNP) | VAF 41/394 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- KCND3 | c.64G>T p.V22L | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNQ3 | c.218G>C p.G73A | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNV2 | c.1070G>C p.G357A | Missense Mutation (SNP) | VAF 36/394 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- KDM6A | c.2518A>T p.S840C | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- KHSRP | c.365A>G p.K122R | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- KIAA0319 | c.3115A>G p.T1039A | Missense Mutation (SNP) | VAF 162/339 reads (48%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KIAA1755 | c.2992C>A p.L998I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- KIR2DL1 | c.784T>G p.F262V | Missense Mutation (SNP) | VAF 24/418 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.77); called by muse, mutect2
- KIR3DL2 | c.447G>T p.M149I | Missense Mutation (SNP) | VAF 126/456 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- KLB | c.2297A>T p.Q766L | Missense Mutation (SNP) | VAF 82/165 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KMT2D | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- KMT2E | c.4906C>G p.P1636A | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.956); called by muse, varscan2
- KRT2 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- KRT23 | c.984C>A p.D328E | Missense Mutation (SNP) | VAF 34/291 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.371); called by muse, mutect2
- KRT24 | c.683A>T p.D228V | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KRT34 | c.561C>A p.Y187* | Nonsense Mutation (SNP) | VAF 31/70 reads (44%) | called by muse, mutect2, varscan2
- KRT6C | c.671A>T p.Q224L | Missense Mutation (SNP) | VAF 132/599 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- KRT73 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT85 | c.203T>C p.V68A | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KRTAP4-9 | c.507C>A p.C169* | Nonsense Mutation (SNP) | VAF 72/380 reads (19%) | called by muse, varscan2
- L1CAM | c.2452C>A p.L818M | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LAG3 | c.404G>T p.W135L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- LAMA5 | c.3051C>G p.Y1017* | Nonsense Mutation (SNP) | VAF 15/121 reads (12%) | called by muse, mutect2, varscan2
- LCE2D | c.254G>C p.R85P | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- LGALS4 | c.554C>A p.P185H | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- LGI2 | c.542G>T p.W181L | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- LHFPL3 | c.495C>A p.Y165* | Nonsense Mutation (SNP) | VAF 129/338 reads (38%) | called by muse, mutect2, varscan2
- LILRA2 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, mutect2
- LILRA4 | c.857G>T p.S286I | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- LILRA6 | c.511C>A p.Q171K | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.061); called by muse, varscan2
- LILRB2 | c.830C>A p.S277Y | Missense Mutation (SNP) | VAF 107/348 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LINC02876 | n.288G>T | Splice Region (SNP) | VAF 125/314 reads (40%) | called by muse, mutect2, varscan2
- LMNB2 | c.1279_1291del p.A427Wfs*144 | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | called by mutect2, pindel, varscan2
- LMOD2 | c.1270C>A p.P424T | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- LPAR5 | c.1058G>T p.R353L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LPXN | c.481G>T p.G161W | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRFN1 | c.152G>T p.C51F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- LRP1 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LRP1 | c.2696G>T p.R899L | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRP1B | c.2393G>T p.C798F | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRRC30 | c.652G>T p.G218C | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRRC7 | c.304-1G>A p.X102_splice (on ENST00000651989 / NM_001370785.2; = p.X69_splice on NM_001330635.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 38/120 reads (32%) | called by muse, mutect2, varscan2
- LRRC72 | c.539G>C p.R180T | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRK2 | c.6704G>T p.R2235I | Missense Mutation (SNP) | VAF 21/276 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.051); called by muse, mutect2
- LTN1 | c.3921G>C p.W1307C | Missense Mutation (SNP) | VAF 59/205 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LUZP2 | c.251G>T p.R84I | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAGEL2 | c.989C>A p.A330D | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MAGI1 | c.4316G>C p.G1439A | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MALRD1 | c.4054C>G p.H1352D | Missense Mutation (SNP) | VAF 187/468 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- MANSC4 | c.602C>A p.A201E | Missense Mutation (SNP) | VAF 67/328 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- MAP1LC3C | c.35C>A p.P12H | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- MAP3K21 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- MAP3K3 | c.4+2T>A p.X2_splice | Splice Site (SNP) | VAF 42/169 reads (25%) | called by muse, mutect2, varscan2
- MAP4K3 | c.979dup p.T327Nfs*13 | Frame Shift Ins (INS) | VAF 165/363 reads (45%) | called by mutect2, pindel, varscan2
- MAST2 | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MAT1A | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCM3AP | c.3224A>G p.Y1075C | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- MDGA2 | c.1312C>A p.L438I (on ENST00000399232 / NM_001113498.2; = p.L140I on NM_182830.4) | Missense Mutation (SNP) | VAF 45/721 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- MEFV | c.1585C>T p.Q529* | Nonsense Mutation (SNP) | VAF 53/217 reads (24%) | called by muse, mutect2, varscan2
- MELTF | c.1484A>T p.Q495L | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- MFSD14A | c.725A>C p.Q242P | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- MLH3 | c.2671G>T p.G891W | Missense Mutation (SNP) | VAF 193/595 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- MLXIP | c.1625A>T p.K542I | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- MOB3B | c.341C>A p.A114D | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPP3 | c.1294G>T p.V432L | Missense Mutation (SNP) | VAF 79/213 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- MROH5 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- MROH5 | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | called by muse, varscan2
- MS4A3 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- MS4A3 | c.584G>T p.W195L | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MS4A5 | c.230C>A p.P77Q | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT tolerated (0.34); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTHFD1L | c.2721G>T p.M907I | Missense Mutation (SNP) | VAF 107/238 reads (45%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- MTIF2 | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 37/271 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- MTUS2 | c.3184G>A p.A1062T (on ENST00000612955 / NM_001366650.1; = p.A41T on NM_015233.6) | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MUC17 | c.12648G>T p.Q4216H | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- MUC22 | c.1894G>T p.G632C | Missense Mutation (SNP) | VAF 126/269 reads (47%) | SIFT deleterious (0.04); called by muse, mutect2, varscan2
- MYH3 | c.1963A>C p.N655H | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MYH7 | c.5688C>A p.F1896L | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.042); called by muse, mutect2
- MYOC | c.916C>A p.Q306K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- MYT1 | c.284A>T p.E95V | Missense Mutation (SNP) | VAF 92/257 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- N4BP2 | c.4483G>A p.E1495K | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- NAA40 | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAV3 | c.1115A>G p.E372G | Missense Mutation (SNP) | VAF 31/497 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.395); called by muse, mutect2
- NAV3 | c.1117G>T p.G373W | Missense Mutation (SNP) | VAF 35/505 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- NBAS | c.1839G>T p.E613D | Missense Mutation (SNP) | VAF 536/703 reads (76%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- NCKAP1 | c.1433G>T p.G478V | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- NCOA5 | c.974G>C p.R325T | Missense Mutation (SNP) | VAF 47/411 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- NCR1 | c.71-1G>A p.X24_splice | Splice Site (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- NEFM | c.520G>T p.D174Y | Missense Mutation (SNP) | VAF 53/273 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NEURL4 | c.3865-3C>T | Splice Region (SNP) | VAF 50/108 reads (46%) | called by muse, mutect2, varscan2
- NHLH1 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- NIN | c.952G>T p.G318C | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NIPBL | c.6016A>G p.I2006V | Missense Mutation (SNP) | VAF 130/270 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.093); called by muse, varscan2
- NKD1 | c.1021G>T p.G341W | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); called by muse, mutect2
- NKD2 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- NKX2-2 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- NLK | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 110/370 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- NOP58 | c.487G>T p.V163F | Missense Mutation (SNP) | VAF 108/199 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- NPAS3 | c.2663C>A p.A888E (on ENST00000356141 / NM_001164749.2; = p.A856E on NM_022123.3) | Missense Mutation (SNP) | VAF 34/478 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); called by muse, mutect2
- NPR1 | c.2869C>G p.R957G | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- NRAP | c.3605G>T p.S1202I (on ENST00000359988 / NM_001322945.2; = p.S1167I on NM_006175.4) | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- NRIP2 | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 63/160 reads (39%) | called by muse, mutect2, varscan2
- NRP1 | c.234G>T p.E78D | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NRXN2 | c.4475C>A p.A1492D | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NSUN4 | c.561G>C p.K187N | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NT5C1B | c.432T>A p.S144R (on ENST00000359846 / NM_001199086.2; = p.S84R on NM_033253.4) | Missense Mutation (SNP) | VAF 170/231 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- NT5C3B | c.134C>G p.T45S | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NT5DC2 | c.757G>C p.V253L | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- NTSR1 | c.1006C>G p.P336A | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- NUP42 | c.409G>T p.V137F | Missense Mutation (SNP) | VAF 44/350 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- NUP58 | c.1228G>T p.V410L | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- OLFM4 | c.899T>A p.L300* | Nonsense Mutation (SNP) | VAF 76/339 reads (22%) | called by muse, varscan2
- OR10G2 | c.431G>T p.R144M | Missense Mutation (SNP) | VAF 26/488 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); called by muse, mutect2
- OR10T2 | c.508T>A p.C170S | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- OR14A2 | c.494C>A p.P165H | Missense Mutation (SNP) | VAF 65/280 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- OR2B6 | c.852G>C p.M284I | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.297); called by muse, mutect2
- OR2C3 | c.171C>A p.H57Q | Missense Mutation (SNP) | VAF 31/308 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- OR2G3 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR2G6 | c.436G>C p.G146R | Missense Mutation (SNP) | VAF 60/291 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- OR2M5 | c.698dup p.R234Sfs*32 | Frame Shift Ins (INS) | VAF 62/458 reads (14%) | called by mutect2, pindel, varscan2
- OR2T10 | c.595A>T p.M199L | Missense Mutation (SNP) | VAF 64/104 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- OR4C15 | c.450C>A p.C150* (on ENST00000314644; = p.C96* on NM_001001920.2) | Nonsense Mutation (SNP) | VAF 27/292 reads (9%) | called by muse, mutect2
- OR4D11 | c.923C>A p.S308Y | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- OR4X1 | c.98A>G p.Y33C | Missense Mutation (SNP) | VAF 67/294 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR52N1 | c.503T>A p.L168H | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR52N4 | c.566T>C p.L189S | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- OR56A5 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5AP2 | c.571C>A p.L191I | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5F1 | c.535T>A p.C179S | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR6Q1 | c.221G>T p.W74L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR8K3 | c.437C>G p.A146G | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- OSBPL11 | c.2179G>A p.G727R | Missense Mutation (SNP) | VAF 51/292 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OTOF | c.5636C>A p.S1879Y (on ENST00000272371 / NM_194248.3; = p.S1112Y on NM_004802.4) | Missense Mutation (SNP) | VAF 79/117 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- OTOG | c.3300C>G p.H1100Q | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OTOGL | c.2466-1G>T p.X822_splice (on ENST00000547103; = p.X813_splice on NM_173591.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 85/189 reads (45%) | called by muse, mutect2, varscan2
- OTOL1 | c.891G>T p.E297D | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- OVCH1 | c.2974G>A p.G992R | Missense Mutation (SNP) | VAF 40/287 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- OVCH1 | c.2522C>A p.S841Y | Missense Mutation (SNP) | VAF 76/352 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- P3H1 | c.1517del p.P506Hfs*36 | Frame Shift Del (DEL) | VAF 26/195 reads (13%) | called by mutect2, pindel, varscan2
- PAG1 | c.571G>T p.A191S | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.085); called by muse, mutect2
- PAN3 | c.1357C>A p.L453M | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- PAOX | c.1140_1141del p.C380Wfs*7 | Frame Shift Del (DEL) | VAF 33/115 reads (29%) | called by pindel, varscan2
- PARG | c.2489G>C p.R830T | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.503); called by muse, mutect2
- PAX2 | c.1027C>A p.P343T (on ENST00000428433 / NM_003987.5; = p.P320T on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAX6 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 216/441 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.282); called by muse, mutect2, varscan2
709 further variants in this file (243 protein-altering or splice-affecting, 287 silent, 179 other) are not listed here.
